Somatic mutation profile of tumor specimen ALCH-B06A-TTP1-A (aliquot ALCH-B06A-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-B06A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.7 years (27,634 days).
Specimen ALCH-B06A-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97aacdaa-5b0a-4143-8150-d2332330b18a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B06A-NB1-A (Blood Derived Normal), aliquot ALCH-B06A-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c9a4350-2912-4c16-a8ba-a126e8ae7767

The open-access MAF lists 171 somatic variants for this specimen: 123 protein-altering or splice-affecting, 35 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 35, Nonsense Mutation 9, Intron 8, Frame Shift Del 3, RNA 2, Splice Site 2, Splice Region 1, In Frame Del 1, 5'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 56/512 reads (11%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- PTEN | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 123/894 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs786204931, CM020755, COSV64290794, COSV64294365; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 41/272 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2776C>G p.H926D | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.326); catalogued as COSV60912522, COSV60917542; called by muse, mutect2
- ACTC1 | c.809-1G>A p.X270_splice | Splice Site (SNP) | VAF 30/211 reads (14%) | catalogued as rs1566967122, COSV51757266; called by muse, mutect2, varscan2
- ADGRA1 | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs763932097; called by muse, varscan2
- ALG13 | c.2300G>A p.G767E | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV52640576; called by muse, mutect2
- ANKRD30A | c.1748C>T p.P583L (on ENST00000611781; = p.P527L on NM_052997.2) | Missense Mutation (SNP) | VAF 38/1346 reads (3%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.981); catalogued as COSV100653551; called by muse, mutect2
- ANKS1B | c.2098G>T p.D700Y | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.459); catalogued as rs746679510; called by muse, mutect2, varscan2
- APC | c.5053G>A p.E1685K | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.534); catalogued as COSV104442106; called by muse, mutect2, varscan2
- ATP4A | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs199790968, COSV52869449; called by muse, mutect2, varscan2
- C7orf26 | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100253901, COSV60106893; called by muse, mutect2
- CAVIN4 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 65/477 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs779838936; called by muse, mutect2, varscan2
- CCT6A | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 34/356 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as rs1421531740; called by muse, mutect2
- CD247 | c.300G>A p.P100= | Splice Region (SNP) | VAF 29/247 reads (12%) | catalogued as rs541120315; called by muse, varscan2
- CTC1 | c.2453G>A p.R818Q | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs772328631, COSV59855497; called by muse, mutect2, varscan2
- DDX10 | c.1004G>T p.R335L | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV59436570; called by muse, mutect2, varscan2
- DLG5 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772926425; called by muse, mutect2, varscan2
- DNHD1 | c.2230G>A p.V744M | Missense Mutation (SNP) | VAF 38/288 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs543737354; called by muse, mutect2, varscan2
- FAM160A1 | c.2524G>A p.V842M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1273013945; called by muse, mutect2, varscan2
- FPR2 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as COSV100389303; called by muse, mutect2, varscan2
- G6PD | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99682432; called by muse, mutect2
- GDF10 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs782250006; called by muse, mutect2, varscan2
- GRID1 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs770855150, COSV60040473; called by muse, mutect2, varscan2
- HLA-A | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV65139114, COSV65141540; called by muse, varscan2
- KCNA6 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 12/81 reads (15%) | catalogued as COSV54978519; called by muse, mutect2, varscan2
- KIF2C | c.1386T>G p.F462L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as rs953255798; called by muse, mutect2
- KLHL5 | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 24/172 reads (14%) | catalogued as COSV54678946; called by muse, mutect2, varscan2
- LRIT3 | c.1079G>C p.R360T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV59983208; called by muse, mutect2
- MYH15 | c.2263G>A p.E755K | Missense Mutation (SNP) | VAF 49/490 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs758897572; called by muse, mutect2
- MYLK | c.1406C>G p.S469C | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs1274976522; called by muse, mutect2
- MYO19 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs772850495; called by muse, mutect2
- OR4P4 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as rs761961138; called by muse, mutect2, varscan2
- ORAI1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs782088694; called by muse, mutect2
- PAK2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 25/204 reads (12%) | catalogued as COSV59086172; called by muse, varscan2
- PKHD1 | c.4540G>A p.D1514N | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV61890944; called by muse, mutect2, varscan2
- PLCH1 | c.2767A>T p.S923C (on ENST00000340059 / NM_001130960.2; = p.S915C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100398078; called by muse, mutect2
- PLPP3 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs1229420952; called by muse, mutect2
- PRKAR1A | c.732G>C p.K244N | Missense Mutation (SNP) | VAF 66/751 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as CD023273; called by muse, mutect2
- PTPN5 | c.274G>C p.A92P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100660004; called by muse, mutect2, varscan2
- RALGAPA1 | c.574C>G p.P192A | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs753654337; called by muse, mutect2, varscan2
- SHANK1 | c.5300G>T p.G1767V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs574089146; called by muse, mutect2, varscan2
- STK3 | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs1199182127; called by mutect2, varscan2
- SYDE2 | c.2527G>C p.E843Q | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1435987970; called by muse, mutect2
- TAF1 | c.2185C>T p.R729C (on ENST00000373790 / NM_138923.4; = p.R750C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52119265; called by muse, mutect2
- TBCCD1 | c.1463C>G p.S488C | Missense Mutation (SNP) | VAF 20/611 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.205); catalogued as COSV58661712; called by muse, mutect2
- THG1L | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 35/345 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1042259041; called by muse, mutect2, varscan2
- THSD7A | c.1296G>T p.W432C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70274192; called by muse, mutect2, varscan2
- TPR | c.4918G>A p.E1640K | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV100823976; called by muse, mutect2
- ZNF174 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 15/383 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1341234345, COSV99237731; called by muse, mutect2
- ZNF415 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199811601; called by muse, mutect2, varscan2
- ABCB5 | c.3458G>T p.G1153V (on ENST00000404938 / NM_001163941.2; = p.G708V on NM_178559.6) | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY9 | c.2982G>C p.W994C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANK3 | c.5114A>G p.K1705R | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ANK3 | c.4076T>G p.V1359G (on ENST00000280772 / NM_001320874.2; = p.V493G on NM_001149.3) | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ANLN | c.2656C>T p.Q886* | Nonsense Mutation (SNP) | VAF 75/492 reads (15%) | called by muse, mutect2, varscan2
- AP1G2 | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.322); called by muse, mutect2
- ARL5B | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); called by muse, mutect2
- ASTE1 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 14/500 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.037); called by muse, mutect2
- BATF3 | c.163A>C p.K55Q | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- BCL7A | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- BEND4 | c.1223A>G p.K408R | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- BICC1 | c.1571A>G p.Q524R | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CASS4 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.545); called by muse, mutect2
- CCDC116 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2
- CDKN2AIP | c.382del p.R128Efs*10 | Frame Shift Del (DEL) | VAF 36/334 reads (11%) | called by mutect2, pindel, varscan2
- CDYL | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- CELF1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- CPNE5 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.99); called by muse, mutect2
- CPS1 | c.934T>C p.S312P | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRYBB3 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CWF19L2 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 17/477 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.091); called by muse, mutect2
- DHX57 | c.2941C>T p.H981Y | Missense Mutation (SNP) | VAF 51/474 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- ESRP2 | c.809A>T p.D270V (on ENST00000565858 / NM_001365264.1; = p.D260V on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ETS2 | c.1045dup p.I349Nfs*44 | Frame Shift Ins (INS) | VAF 15/122 reads (12%) | called by mutect2, pindel
- FAM120C | c.2759C>A p.S920Y | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- FAT2 | c.8329G>A p.V2777M | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- FCGR3A | c.676T>C p.Y226H | Missense Mutation (SNP) | VAF 27/375 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2
- GAB4 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- GJD2 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by mutect2, varscan2
- GPCPD1 | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.034); called by muse, varscan2
- GSG1 | c.982G>C p.E328Q (on ENST00000651961 / NM_001080555.4; = p.E292Q on NM_153823.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); called by muse, mutect2
- GTF2I | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- HS3ST5 | c.802C>A p.L268I | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2
- IP6K2 | c.1040C>G p.S347* | Nonsense Mutation (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- JAK3 | c.2598G>T p.R866S | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- KDM2B | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- LAMA3 | c.5949G>T p.R1983S (on ENST00000313654 / NM_198129.4; = p.R374S on NM_000227.6) | Missense Mutation (SNP) | VAF 11/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LIN9 | c.692G>A p.R231K (on ENST00000366808 / NM_001270410.2; = p.R176K on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/508 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); called by muse, mutect2
- MAEL | c.334G>C p.G112R | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MAGED2 | c.1520T>G p.L507R | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); called by muse, mutect2
- MAN2A1 | c.2899G>C p.E967Q | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.044); called by muse, mutect2
- MED12 | c.6160C>T p.Q2054* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | called by muse, varscan2
- MRPL55 | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP11 | c.622C>G p.P208A | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR51A4 | c.594del p.I199Sfs*12 | Frame Shift Del (DEL) | VAF 39/210 reads (19%) | called by mutect2, pindel*, varscan2
- PALB2 | c.2587-1G>A p.X863_splice | Splice Site (SNP) | VAF 36/223 reads (16%) | called by muse, mutect2, varscan2
- PDE8B | c.903G>T p.M301I | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.021); called by muse, mutect2
- PEX1 | c.3345G>C p.E1115D | Missense Mutation (SNP) | VAF 20/543 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- PIK3C3 | c.2373G>C p.Q791H | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIK3CG | c.3067C>A p.H1023N | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PIWIL2 | c.2699G>A p.C900Y | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- PLAT | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- PPP1R2B | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2
- PPP2CA | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- PTPN13 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 15/426 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2
- RB1 | c.2228del p.L743* | Frame Shift Del (DEL) | VAF 36/307 reads (12%) | called by mutect2, pindel, varscan2
- RGS2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 42/384 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.905); called by muse, mutect2
- SMG8 | c.2726G>T p.R909M | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYNE2 | c.2294C>A p.S765* | Nonsense Mutation (SNP) | VAF 25/745 reads (3%) | called by muse, mutect2
- SYNPO2L | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2
- TEX14 | c.68T>A p.L23Q | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- THBS3 | c.1622A>T p.N541I | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- THBS4 | c.1265G>T p.R422I | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP53BP1 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 13/343 reads (4%) | called by muse, mutect2
- TRGV10 | c.113G>A p.C38Y | Missense Mutation (SNP) | VAF 70/434 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRIM64B | c.344C>G p.S115C | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2
- TSC22D3 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TTN | c.31429G>A p.E10477K (on ENST00000591111; = p.E9550K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/292 reads (11%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USH2A | c.14102A>C p.E4701A | Missense Mutation (SNP) | VAF 54/514 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- USP47 | c.3619G>A p.E1207K (on ENST00000399455 / NM_001372095.1; = p.E1119K on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/616 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- VPS54 | c.1326G>C p.L442F | Missense Mutation (SNP) | VAF 62/546 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- XIRP2 | c.1913A>G p.E638G (on ENST00000628543; = p.E813G on NM_152381.6) | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAMTSL1 | c.4086G>C p.L1362= | Silent (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- ADGRA3 | c.3399C>T p.N1133= | Silent (SNP) | VAF 17/102 reads (17%) | called by muse, mutect2, varscan2
- AGL | c.1086G>A p.K362= | Silent (SNP) | VAF 21/547 reads (4%) | called by muse, mutect2
- ASS1 | c.714C>G p.V238= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as rs1252459333; called by muse, mutect2
- ATP7A | c.66T>C p.C22= | Silent (SNP) | VAF 80/366 reads (22%) | called by muse, mutect2, varscan2
- CACNA1E | c.3513G>A p.A1171= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs565145928, COSV62433924; called by mutect2, varscan2
- CDH12 | c.330C>T p.D110= | Silent (SNP) | VAF 123/436 reads (28%) | called by muse, mutect2, varscan2
- CFAP92 | c.2064C>T p.L688= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs1373840610; called by muse, mutect2
- CNPY4 | c.231G>A p.V77= | Silent (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- DNAJC1 | c.1329G>A p.R443= | Silent (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- EPC1 | c.1146C>T p.L382= | Silent (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2, varscan2
- EVX1 | c.324G>A p.G108= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs1311720734; called by muse, mutect2, varscan2
- FAT4 | c.10995G>T p.G3665= | Silent (SNP) | VAF 37/313 reads (12%) | called by muse, mutect2, varscan2
- FLYWCH1 | c.135C>G p.L45= | Silent (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- GABRA5 | c.198C>T p.P66= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs372457430; called by muse, mutect2, varscan2
- HSPA5 | c.1905T>C p.Y635= | Silent (SNP) | VAF 24/219 reads (11%) | catalogued as rs370345641; called by muse, mutect2, varscan2
- MCM7 | c.2112C>G p.L704= | Silent (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- MERTK | c.816G>A p.V272= | Silent (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- MYO18B | c.6219C>T p.S2073= | Silent (SNP) | VAF 29/133 reads (22%) | called by muse, mutect2, varscan2
- OR2T6 | c.138C>A p.I46= | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- OTUD4 | c.1020G>T p.V340= (on ENST00000447906 / NM_001366057.1; = p.V275= on NM_001102653.1) | Silent (SNP) | VAF 21/252 reads (8%) | catalogued as rs1369287694; called by muse, mutect2
- PCBP1 | c.181C>T p.L61= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- PLA2G4D | c.1042C>T p.L348= | Silent (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- PRPF19 | c.60C>T p.V20= | Silent (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- RASSF4 | c.234G>A p.V78= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs200440565; called by muse, mutect2, varscan2
- RBM19 | c.2268G>A p.V756= | Silent (SNP) | VAF 15/346 reads (4%) | called by muse, mutect2
- SEC61A1 | c.546C>T p.F182= | Silent (SNP) | VAF 20/394 reads (5%) | called by muse, mutect2
- SOX4 | c.819G>T p.S273= | Silent (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- SURF6 | c.312G>C p.L104= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV63292828; called by muse, mutect2, varscan2
- TTC3 | c.591C>T p.F197= | Silent (SNP) | VAF 54/423 reads (13%) | called by muse, mutect2, varscan2
- VPS35 | c.51T>C p.D17= | Silent (SNP) | VAF 59/624 reads (9%) | catalogued as rs770188899; called by muse, mutect2
- WDR87 | c.7422C>A p.T2474= | Silent (SNP) | VAF 25/199 reads (13%) | called by muse, mutect2, varscan2
- ZNF107 | c.219C>T p.S73= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV100788311; called by muse, mutect2, varscan2
- ZNF254 | c.789G>A p.E263= | Silent (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- ZNF32 | c.642G>A p.L214= | Silent (SNP) | VAF 9/225 reads (4%) | catalogued as COSV65641727; called by muse, mutect2
- ANKK1 | chr11:113383386 G>T | 5'Flank (SNP) | VAF 67/385 reads (17%) | called by muse, mutect2, varscan2
- COL5A3 | c.4153-72A>G | Intron (SNP) | VAF 12/131 reads (9%) | called by muse, mutect2
- FAM86DP | n.490G>T | RNA (SNP) | VAF 18/171 reads (11%) | called by muse, mutect2, varscan2
- GABRG2 | c.1248+299C>T | Intron (SNP) | VAF 26/430 reads (6%) | called by muse, mutect2
- HAPLN4 | c.-46C>A | 5'UTR (SNP) | VAF 4/27 reads (15%) | catalogued as rs753504837; called by muse, mutect2, varscan2
- MAU2 | c.1309-86A>G | Intron (SNP) | VAF 15/83 reads (18%) | catalogued as rs1430729502; called by muse, mutect2, varscan2
- MIR376A1 | n.46C>G | RNA (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2, varscan2
- N4BP2L1 | c.307+114T>C | Intron (SNP) | VAF 18/303 reads (6%) | called by muse, mutect2
- PNPO | c.417+19G>C | Intron (SNP) | VAF 34/276 reads (12%) | called by muse, mutect2, varscan2
- PRMT2 | c.654+2230C>G | Intron (SNP) | VAF 11/158 reads (7%) | catalogued as COSV99388675, COSV99388771; called by muse, mutect2
- SDK2 | c.5593+88C>T | Intron (SNP) | VAF 42/157 reads (27%) | called by muse, mutect2, varscan2
- TPI1 | c.*84G>T | 3'UTR (SNP) | VAF 65/706 reads (9%) | called by muse, mutect2
- UBP1 | c.1271+208T>C | Intron (SNP) | VAF 34/362 reads (9%) | catalogued as rs1404994446; called by muse, mutect2
